Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7252, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7252-01A (Primary Tumor).

[page 1 of 2]
Received:

Pathologist:

Accession:

Case type: Surgical History

** Case imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to the section "SPECIMEN" may have been added. **

SUPPLEMENTAL REPORT

RECD: PATH DOB: #
FINAL DATE

CONSULTANT

PHOTO: NO
DX COMPLETED

D:N
DIAGNOSIS :

SUPPLEMENTAL REPORT

COMMENT: The invasive squamous carcinoma in specimen C (hemiglossectomy, maxillectomy, mandibulectomy, partial pharyngectomy and neck dissection) infiltrates the mandibular bone, however, the mandibular bone resection margins are negative for tumor.

Fragments of bone designated with attached soft tissue, negative for tumor.

DIAGNOSIS

- (A) BUCCAL MUCOSA, RIGHT, EXCISION:
FRAGMENTS OF WELL DIFFERENTIATED SQUAMOUS CARCINOMA.
Invasion cannot be evaluated in this material.
- (B) NODULE, SUBMENTAL, EXCISION:
Fragments of lymphoid tissue, negative for tumor.
- (C) HEMIGLOSSECTOMY, MAXILLECTOMY, MANDIBULECTOMY, PARTIAL PHARYNGECTOMY AND NECK DISSECTION:
INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED, INVOLVING BUCCAL MUCOSA, GINGIVA, PHARYNX AND TONGUE.
(SEE COMMENT)
TUMOR EXTENDS TO LATERAL SOFT TISSUE RESECTION MARGIN.
Anterior, medial, posterior and deep resection margins are negative for tumor.
Perineural invasion is present.
Submandibular gland with chronic inflammatory cell infiltrate, negative for tumor.
Thirty-one left neck dissection lymph nodes, negative for tumor (4 submental, 1 subdigastric, 4 midjugular, 5 lower jugular, 1 upper posterior cervical, 4 midposterior cervical, and 12 lower posterior cervical).
Mandibular bone is being decalcified and a supplemental report will follow.
- (D) UVULA, REMNANT, EXCISION:
Squamous mucosa and salivary gland tissue, negative for tumor.

[page 2 of 2]
COMMENT

The squamous carcinoma in specimen C measures 5.5 x 3.0 x 3.0 cm.
The tumor has grossly a 2.5 cm depth of invasion.

SPECIMEN

- (A) BUCCAL MUCOSA, RIGHT, EXCISION:
- (B) NODULE, SUBMENTAL, EXCISION:
- (C) HEMIGLOSSECTOMY, MAXILLECTOMY, MANDIBULECTOMY, PARTIAL PHARYNGECTOMY AND
- (D) UVULA, REMNANT, EXCISION:

SNOMED CODES

T-51300,M-Y4973

Source: NCI Genomic Data Commons file e6305bb8-0cc8-42ff-9c0c-97c95b9d0e24 (TCGA-CV-7252.5F50C33A-9AA8-4868-91C1-0B30304ECC9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).